FM case AD6265 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/def896e1-ee5c-4ba5-b0ed-8db99efc5d12

Male, 27.9 years: diagnosis not reported by GDC; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
